Somatic mutation profile of tumor specimen 0DD873 from CCDI case PBBNIR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.7 years (244 days).
Specimen 0DD873: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d4c8937-b839-4543-b0e1-c55cabaed2ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD86X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dd86aef-4fbb-49ab-9d98-e32d9ca6d10b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXIN2 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 27/453 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs765865516, COSV61056803; ClinVar: uncertain significance; called by muse, mutect2
- MPI | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
